Somatic mutation profile of tumor specimen ALCH-B0CQ-TTP1-A (aliquot ALCH-B0CQ-TTP1-A-5-0-D-A694-36) from ALCHEMIST case ALCH-B0CQ, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 51.3 years (18,732 days).
Specimen ALCH-B0CQ-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a967ff77-1302-456a-83ba-1b788ddf2e13.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B0CQ-NB1-A (Blood Derived Normal), aliquot ALCH-B0CQ-NB1-A-1-0-D-A695-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e93ad242-b48a-4b75-bd71-0d94a9e764f0

The open-access MAF lists 145 somatic variants for this specimen: 99 protein-altering or splice-affecting, 30 silent, 16 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 81, Silent 30, Nonsense Mutation 15, Intron 7, 5'UTR 3, RNA 3, 5'Flank 3, Frame Shift Del 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 76/305 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.361C>A p.L121M | Missense Mutation (SNP) | VAF 61/244 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV70032133; called by muse, mutect2, varscan2
- ACVRL1 | c.89C>T p.P30L | Missense Mutation (SNP) | VAF 16/188 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs765215717; called by muse, mutect2
- ANK2 | c.1397C>T p.T466M | Missense Mutation (SNP) | VAF 28/400 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs786205722, COSV52161357; ClinVar: uncertain significance; called by muse, mutect2
- BIRC2 | c.482T>C p.L161P | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as rs1405505936; called by muse, mutect2, varscan2
- CAND2 | c.2567C>T p.P856L (on ENST00000456430 / NM_001162499.2; = p.P763L on NM_012298.3) | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1239015595; called by muse, mutect2, varscan2
- CELA3A | c.339G>A p.W113* | Nonsense Mutation (SNP) | VAF 14/69 reads (20%) | catalogued as rs374012083; called by muse, mutect2, varscan2
- CNPY1 | c.61G>C p.A21P | Missense Mutation (SNP) | VAF 14/210 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1344924963, COSV58786479; called by muse, mutect2
- COL3A1 | c.743C>A p.P248Q | Missense Mutation (SNP) | VAF 49/257 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV58588017; called by muse, mutect2, varscan2
- CSMD3 | c.4825C>A p.P1609T (on ENST00000297405 / NM_001363185.1; = p.P1505T on NM_052900.3) | Missense Mutation (SNP) | VAF 61/358 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV52313045; called by muse, mutect2, varscan2
- DMXL1 | c.4462G>A p.V1488I | Missense Mutation (SNP) | VAF 23/266 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.517); catalogued as rs1203301627; called by muse, mutect2
- DVL3 | c.1393C>T p.R465C | Missense Mutation (SNP) | VAF 13/211 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1463261176, COSV100493500; called by muse, mutect2
- EYS | c.695G>T p.R232I | Missense Mutation (SNP) | VAF 15/133 reads (11%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.621); catalogued as COSV60993277; called by muse, mutect2, varscan2
- FMN2 | c.5099G>T p.G1700V | Missense Mutation (SNP) | VAF 18/230 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.247); catalogued as COSV60420981; called by muse, mutect2
- FOXF2 | c.427G>T p.G143C | Missense Mutation (SNP) | VAF 20/240 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779367418; called by muse, mutect2
- FPR1 | c.739G>A p.A247T | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.164); catalogued as rs764370052, COSV59050822; called by muse, mutect2, varscan2
- HERC2 | c.709G>T p.E237* | Nonsense Mutation (SNP) | VAF 14/115 reads (12%) | catalogued as COSV55348491; called by muse, mutect2, varscan2
- IGKV1D-17 | c.202C>T p.H68Y | Missense Mutation (SNP) | VAF 36/463 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs1257952822; called by muse, mutect2
- ITGB7 | c.68C>T p.A23V | Missense Mutation (SNP) | VAF 27/186 reads (15%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as rs984488140; called by muse, mutect2, varscan2
- LHX6 | c.164C>T p.P55L (on ENST00000373755 / NM_001242334.2; = p.P84L on NM_014368.5) | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.778); catalogued as rs899943755; called by muse, mutect2, varscan2
- MAP7D3 | c.368G>T p.R123L | Missense Mutation (SNP) | VAF 40/157 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60170113; called by muse, mutect2, varscan2
- MGAM | c.2042del p.P681Rfs*26 | Frame Shift Del (DEL) | VAF 54/270 reads (20%) | catalogued as COSV101527738; called by mutect2, pindel, varscan2
- MUC12 | c.892C>A p.R298S (on ENST00000379442; = p.R155S on NM_001164462.1) | Missense Mutation (SNP) | VAF 24/246 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs571855490, COSV65198830; called by muse, mutect2
- NAALADL1 | c.592C>A p.R198S | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60525110; called by muse, mutect2, varscan2
- NUDT12 | c.610G>C p.E204Q | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated (0.71); PolyPhen benign (0.01); catalogued as COSV50091691; called by muse, mutect2
- OR2G6 | c.425C>T p.A142V | Missense Mutation (SNP) | VAF 16/254 reads (6%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as rs143730398, COSV58574053; called by muse, mutect2
- OR4M1 | c.508G>T p.G170W | Missense Mutation (SNP) | VAF 25/472 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV60059646, COSV60062129; called by muse, mutect2
- PCDHB13 | c.2135G>T p.R712L | Missense Mutation (SNP) | VAF 22/178 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.029); catalogued as rs576971217, COSV53397023, COSV99507003; called by muse, mutect2
- PCDHB3 | c.1081G>T p.G361* | Nonsense Mutation (SNP) | VAF 10/77 reads (13%) | catalogued as COSV50627846; called by muse, varscan2
- PEG3 | c.2055T>A p.C685* | Nonsense Mutation (SNP) | VAF 30/174 reads (17%) | catalogued as COSV55646382; called by muse, mutect2, varscan2
- PRB4 | c.101G>T p.G34V | Missense Mutation (SNP) | VAF 34/214 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.988); catalogued as COSV99686927; called by muse, varscan2
- PYHIN1 | c.1381G>T p.A461S | Missense Mutation (SNP) | VAF 84/248 reads (34%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.094); catalogued as COSV63729560; called by muse, mutect2, varscan2
- RYR2 | c.14695G>T p.D4899Y | Missense Mutation (SNP) | VAF 10/168 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63711452; called by muse, mutect2
- SLC3A1 | c.154C>A p.L52I | Missense Mutation (SNP) | VAF 24/183 reads (13%) | SIFT tolerated (0.42); PolyPhen benign (0.015); catalogued as COSV53226119; called by muse, mutect2, varscan2
- SPTA1 | c.4819A>T p.S1607C | Missense Mutation (SNP) | VAF 146/511 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV63753980; called by muse, varscan2
- TFAP2B | c.1309A>T p.T437S | Missense Mutation (SNP) | VAF 89/317 reads (28%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV53830223; called by muse, mutect2, varscan2
- ZNF284 | c.1207G>T p.G403* | Nonsense Mutation (SNP) | VAF 19/75 reads (25%) | catalogued as COSV101399072, COSV69691640; called by muse, mutect2, varscan2
- ABCC5 | c.1156G>T p.E386* | Nonsense Mutation (SNP) | VAF 5/58 reads (9%) | called by muse, mutect2
- ADAMTS12 | c.1436A>T p.Q479L | Missense Mutation (SNP) | VAF 26/256 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- ARHGAP4 | c.2356G>T p.G786W | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ART5 | c.602C>G p.S201C | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- BEST3 | c.753C>A p.C251* | Nonsense Mutation (SNP) | VAF 20/186 reads (11%) | called by muse, mutect2
- BLMH | c.245T>A p.M82K | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- CDH7 | c.2045C>A p.T682N | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0.173); called by muse, mutect2
- CHCHD4 | c.121G>T p.G41* (on ENST00000396914 / NM_001098502.2; = p.G54* on NM_144636.3) | Nonsense Mutation (SNP) | VAF 25/193 reads (13%) | called by muse, mutect2, varscan2
- CMTR1 | c.1616G>A p.W539* | Nonsense Mutation (SNP) | VAF 13/96 reads (14%) | called by muse, mutect2, varscan2
- COL3A1 | c.3834G>T p.W1278C | Missense Mutation (SNP) | VAF 17/120 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CRABP2 | c.253C>A p.L85M | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.522); called by muse, mutect2
- CRY1 | c.1532G>T p.G511V | Missense Mutation (SNP) | VAF 33/159 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- DCAF4L2 | c.764G>C p.C255S | Missense Mutation (SNP) | VAF 17/270 reads (6%) | SIFT tolerated (0.89); PolyPhen benign (0.001); called by muse, mutect2
- DIDO1 | c.3536G>A p.G1179E | Missense Mutation (SNP) | VAF 24/243 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DIRAS2 | c.373G>T p.E125* | Nonsense Mutation (SNP) | VAF 24/171 reads (14%) | called by muse, mutect2, varscan2
- DMD | c.7064A>T p.N2355I | Missense Mutation (SNP) | VAF 25/113 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DNAH10 | c.1636T>C p.Y546H (on ENST00000409039; = p.Y485H on NM_207437.3) | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (0.46); PolyPhen benign (0.007); called by muse, varscan2
- DOCK2 | c.3973C>A p.Q1325K | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- EDIL3 | c.860C>A p.P287H | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- EML6 | c.725G>C p.S242T | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT tolerated (0.64); PolyPhen benign (0.402); called by muse, mutect2
- F10 | c.1317G>A p.W439* | Nonsense Mutation (SNP) | VAF 6/28 reads (21%) | called by muse, mutect2, varscan2
- FAM124B | c.1265G>C p.G422A | Missense Mutation (SNP) | VAF 22/130 reads (17%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.572); called by muse, mutect2, varscan2
- FBXW7 | c.1448T>C p.L483P (on ENST00000281708 / NM_001349798.2; = p.L403P on NM_018315.5) | Missense Mutation (SNP) | VAF 10/133 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FCGBP | c.4289C>A p.P1430Q | Missense Mutation (SNP) | VAF 24/111 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.534); called by muse, mutect2, varscan2
- GLUD1 | c.1425A>C p.E475D | Missense Mutation (SNP) | VAF 51/274 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.405); called by muse, mutect2, varscan2
- GRIA2 | c.1410G>T p.K470N | Missense Mutation (SNP) | VAF 40/364 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- IL25 | c.420C>G p.F140L | Missense Mutation (SNP) | VAF 29/265 reads (11%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.526); called by muse, mutect2, varscan2
- IQGAP2 | c.1099A>G p.I367V | Missense Mutation (SNP) | VAF 10/113 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- ITGA2B | c.2027A>G p.Y676C | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ITK | c.1853C>G p.S618* | Nonsense Mutation (SNP) | VAF 98/493 reads (20%) | called by muse, mutect2, varscan2
- MUC5B | c.1157C>T p.P386L | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.795); called by muse, mutect2
- MYT1L | c.2653C>A p.L885M | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NAGLU | c.320_340del p.Q107_P113del | In Frame Del (DEL) | VAF 4/53 reads (8%) | called by mutect2, pindel
- NAPB | c.162G>T p.M54I | Missense Mutation (SNP) | VAF 28/140 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NPAS4 | c.68T>A p.L23H | Missense Mutation (SNP) | VAF 34/155 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NPHP4 | c.2132C>T p.T711I | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.141); called by muse, mutect2, varscan2
- PCLO | c.8300A>T p.Q2767L | Missense Mutation (SNP) | VAF 22/124 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.308); called by muse, mutect2, varscan2
- PCNT | c.1175A>G p.E392G | Missense Mutation (SNP) | VAF 38/316 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- PDE9A | c.891G>T p.R297S | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PGK2 | c.137G>T p.S46I | Missense Mutation (SNP) | VAF 58/296 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- PRB4 | c.139C>A p.P47T | Missense Mutation (SNP) | VAF 40/196 reads (20%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.007); called by muse, varscan2
- PRPF8 | c.6122C>T p.A2041V | Missense Mutation (SNP) | VAF 48/470 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.423); called by muse, mutect2
- PTK7 | c.2641G>T p.G881* | Nonsense Mutation (SNP) | VAF 13/116 reads (11%) | called by muse, varscan2
- RBL2 | c.2687T>C p.I896T | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); called by muse, mutect2
- RBM15B | c.2029C>A p.H677N | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT tolerated (0.6); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- RESF1 | c.382G>A p.V128M | Missense Mutation (SNP) | VAF 8/91 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.023); called by muse, mutect2
- RTP3 | c.311C>G p.P104R | Missense Mutation (SNP) | VAF 43/206 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SAMD9 | c.1724G>T p.C575F | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- SAMD9L | c.4555A>T p.K1519* | Nonsense Mutation (SNP) | VAF 10/65 reads (15%) | called by muse, mutect2, varscan2
- SETBP1 | c.2362G>T p.G788C | Missense Mutation (SNP) | VAF 44/405 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SPTBN4 | c.4475C>A p.A1492E | Missense Mutation (SNP) | VAF 34/99 reads (34%) | SIFT tolerated (0.3); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- TANGO2 | c.788C>G p.S263C | Missense Mutation (SNP) | VAF 22/137 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- TTN | c.25695C>A p.N8565K (on ENST00000591111; = p.N7638K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/353 reads (10%) | PolyPhen benign (0.194); called by muse, mutect2
- VPREB1 | c.8G>T p.W3L | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- VWA8 | c.3633G>T p.K1211N | Missense Mutation (SNP) | VAF 29/220 reads (13%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, varscan2
- WDR33 | c.2033A>C p.Q678P | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- XAGE3 | c.146G>C p.G49A | Missense Mutation (SNP) | VAF 12/203 reads (6%) | SIFT tolerated (0.85); PolyPhen possibly damaging (0.727); called by muse, mutect2
- ZAN | c.4776del p.I1593Sfs*12 | Frame Shift Del (DEL) | VAF 26/125 reads (21%) | called by mutect2, pindel, varscan2
- ZC3H12A | c.814G>T p.D272Y | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, varscan2
- ZNF600 | c.1399G>T p.E467* | Nonsense Mutation (SNP) | VAF 28/201 reads (14%) | called by muse, mutect2, varscan2
- ZNF704 | c.1054G>A p.V352M | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF98 | c.1670A>C p.N557T | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT tolerated (0.56); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- ADGRL2 | c.3030G>T p.V1010= (on ENST00000370717 / NM_001366005.1; = p.V997= on NM_012302.4) | Silent (SNP) | VAF 25/106 reads (24%) | called by muse, mutect2, varscan2
- CAPN10 | c.585C>T p.G195= | Silent (SNP) | VAF 53/209 reads (25%) | called by muse, mutect2, varscan2
- CBLIF | c.921C>A p.T307= | Silent (SNP) | VAF 16/548 reads (3%) | called by muse, mutect2
- CLIP2 | c.2350C>A p.R784= | Silent (SNP) | VAF 5/65 reads (8%) | called by muse, mutect2
- COL15A1 | c.2313C>T p.D771= | Silent (SNP) | VAF 18/220 reads (8%) | called by muse, mutect2
- DCHS1 | c.1458G>T p.A486= | Silent (SNP) | VAF 33/242 reads (14%) | called by muse, mutect2, varscan2
- DENND1A | c.687C>T p.P229= | Silent (SNP) | VAF 8/60 reads (13%) | catalogued as rs765331388; called by muse, mutect2, varscan2
- DLGAP4 | c.813C>T p.P271= | Silent (SNP) | VAF 14/138 reads (10%) | catalogued as rs756938520; called by muse, mutect2, varscan2
- DNAJB14 | c.48G>T p.R16= | Silent (SNP) | VAF 18/161 reads (11%) | called by muse, mutect2, varscan2
- FRG2 | c.687C>A p.T229= | Silent (SNP) | VAF 10/231 reads (4%) | catalogued as COSV66459938; called by muse, varscan2
- FRYL | c.5481G>T p.G1827= | Silent (SNP) | VAF 36/207 reads (17%) | called by muse, mutect2, varscan2
- FUS | c.1545T>G p.G515= | Silent (SNP) | VAF 70/204 reads (34%) | catalogued as rs775460018; called by mutect2, varscan2
- HBP1 | c.795A>G p.L265= | Silent (SNP) | VAF 15/121 reads (12%) | called by muse, mutect2, varscan2
- ITSN1 | c.3774G>T p.L1258= | Silent (SNP) | VAF 18/106 reads (17%) | called by muse, mutect2, varscan2
- LOXHD1 | c.4129C>A p.R1377= | Silent (SNP) | VAF 24/242 reads (10%) | catalogued as rs746252931, COSV56061072; called by muse, mutect2, varscan2
- MYH13 | c.276C>A p.A92= | Silent (SNP) | VAF 52/318 reads (16%) | called by muse, mutect2, varscan2
- MYH3 | c.1818G>T p.V606= | Silent (SNP) | VAF 29/222 reads (13%) | called by muse, mutect2, varscan2
- NDST1 | c.1302G>T p.S434= | Silent (SNP) | VAF 27/144 reads (19%) | called by muse, mutect2, varscan2
- NDST3 | c.1515T>G p.L505= | Silent (SNP) | VAF 17/106 reads (16%) | called by muse, mutect2, varscan2
- NRG2 | c.1575T>C p.R525= | Silent (SNP) | VAF 31/104 reads (30%) | called by muse, mutect2, varscan2
- OTOG | c.5304C>A p.T1768= | Silent (SNP) | VAF 7/39 reads (18%) | called by muse, mutect2, varscan2
- PNP | c.270G>T p.G90= | Silent (SNP) | VAF 22/234 reads (9%) | called by muse, mutect2
- POLR3B | c.3087C>T p.A1029= | Silent (SNP) | VAF 9/162 reads (6%) | catalogued as rs886048901; ClinVar: uncertain significance; called by muse, mutect2
- SLC8A1 | c.1998T>A p.A666= | Silent (SNP) | VAF 12/148 reads (8%) | called by muse, mutect2
- SLFN14 | c.556T>C p.L186= | Silent (SNP) | VAF 31/197 reads (16%) | called by muse, mutect2, varscan2
- STYXL2 | c.513C>T p.G171= | Silent (SNP) | VAF 142/573 reads (25%) | catalogued as rs771882329, COSV54810488; called by muse, mutect2, varscan2
- TLR4 | c.1239C>A p.T413= (on ENST00000355622 / NM_138554.5; = p.T373= on NM_003266.4) | Silent (SNP) | VAF 17/127 reads (13%) | called by muse, mutect2, varscan2
- TTN | c.33744A>G p.V11248= (on ENST00000591111; = p.V10321= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 4/44 reads (9%) | catalogued as COSV100623539; called by muse, mutect2
- WDR72 | c.2823T>G p.A941= | Silent (SNP) | VAF 19/137 reads (14%) | called by muse, mutect2, varscan2
- ZNF532 | c.1041C>G p.S347= | Silent (SNP) | VAF 10/103 reads (10%) | called by muse, mutect2
- ACKR1 | c.-83T>A | 5'UTR (SNP) | VAF 24/147 reads (16%) | called by muse, mutect2, varscan2
- AL353804.4 | chrX:73825609 A>C | 5'Flank (SNP) | VAF 14/99 reads (14%) | called by muse, mutect2, varscan2
- BCAT1 | c.7-1062G>A | Intron (SNP) | VAF 19/58 reads (33%) | called by muse, mutect2, varscan2
- C10orf88B | n.638A>T | RNA (SNP) | VAF 33/148 reads (22%) | called by muse, mutect2, varscan2
- C11orf58 | c.148-50A>T | Intron (SNP) | VAF 10/84 reads (12%) | called by muse, mutect2, varscan2
- CHRNA4 | chr20:63361363 C>T | 5'Flank (SNP) | VAF 3/14 reads (21%) | called by muse, mutect2
- EIF1B | c.-7G>T | 5'UTR (SNP) | VAF 17/102 reads (17%) | called by muse, mutect2, varscan2
- FBRSL1 | c.645+3472G>T | Intron (SNP) | VAF 30/117 reads (26%) | catalogued as rs777752674; called by muse, mutect2, varscan2
- GVINP1 | n.2258C>T | RNA (SNP) | VAF 34/243 reads (14%) | called by muse, mutect2, varscan2
- IL36B | c.261+965C>G | Intron (SNP) | VAF 20/355 reads (6%) | called by muse, mutect2
- LAX1 | c.-185C>T | 5'UTR (SNP) | VAF 43/191 reads (23%) | called by muse, mutect2, varscan2
- MAX | c.295+519G>A | Intron (SNP) | VAF 73/625 reads (12%) | called by muse, mutect2, varscan2
- NOC2LP2 | n.865C>A | RNA (SNP) | VAF 38/179 reads (21%) | called by muse, mutect2, varscan2
- PPFIBP1 | c.471+42A>T | Intron (SNP) | VAF 16/52 reads (31%) | called by muse, mutect2
- SORBS2 | c.-45-3878G>A | Intron (SNP) | VAF 34/269 reads (13%) | catalogued as rs564716178; called by muse, mutect2, varscan2
- SUPT5H | chr19:39439795 A>T | 5'Flank (SNP) | VAF 15/50 reads (30%) | called by muse, mutect2
